Gene-level copy-number profile of tumor specimen ALCH-ABOK-TTP1-A from ALCHEMIST case ALCH-ABOK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,573 days).
Specimen ALCH-ABOK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 543a1e12-1f5b-4f26-bfad-c552f500224b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABOK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/551a09b7-13fd-4289-9f44-82c1f273fbdc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 444; copy number 2: 56,309; copy number 3: 1,595; copy number 4: 14; copy number 5: 6; copy number 6: 3; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 5: RPL23AP88.
- chr5:135,802,985–135,803,075, 1 gene, copy number 6: MIR5692C1.
- chr7:6,952,625–7,104,482, 3 genes, copy number 5 (within-gene range 3–5): AC079804.3, MIR3683, AC092104.1.
- chr15:28,332,237–28,358,080, 3 genes, copy number 7: HERC2P1, AC091304.4, AC091304.1.
- chr15:28,422,172–28,426,584, 2 genes, copy number 5: AC091304.5, MIR4509-2.
- chr21:43,414,483–43,453,902, 2 genes, copy number 6–7: SIK1, LINC00319.
- chr21:44,133,610–44,210,114, 1 gene, copy number 6 (within-gene range 2–6): GATD3A.

Autosomal genes at a single copy (total copy number 1): 441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
